Somatic mutation profile of tumor specimen C3N-00150-03 (aliquot CPT0066500009) from CPTAC case C3N-00150, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 55.5 years (20,286 days).
Specimen C3N-00150-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1e3b8eb-2aa3-4f87-b5eb-9d1b5f17bfa6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00150-31 (Blood Derived Normal), aliquot CPT0071650002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9492ea1f-db02-44b5-b959-7507d2f71e19

The open-access MAF lists 53 somatic variants for this specimen: 39 protein-altering or splice-affecting, 5 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 5, Splice Site 4, Intron 3, 3'UTR 2, 5'UTR 1, Frame Shift Del 1, 5'Flank 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEMIP | c.965-1G>C p.X322_splice | Splice Site (SNP) | VAF 24/240 reads (10%) | catalogued as rs769389649; called by muse, mutect2
- CNN2 | c.603G>A p.M201I | Missense Mutation (SNP) | VAF 28/378 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.211); catalogued as rs141801176, COSV99565612; called by muse, mutect2
- CTNNA1 | c.1057G>C p.G353R | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.315); catalogued as rs758284033; ClinVar: uncertain significance; called by muse, mutect2
- DHCR7 | c.760T>C p.S254P | Missense Mutation (SNP) | VAF 42/448 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as CM034225; called by muse, mutect2
- DMXL2 | c.3242G>A p.R1081H | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757597201; called by muse, mutect2, varscan2
- DNAJB5 | c.8A>G p.K3R | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.866); catalogued as rs1272825498; called by muse, mutect2
- HNRNPUL2 | c.1003G>T p.G335C | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV57131444; called by muse, mutect2, varscan2
- OTOF | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.099); catalogued as rs141475833, COSV99716952; called by muse, mutect2
- RASGRP4 | c.1477C>G p.R493G | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.14); catalogued as COSV53039900, COSV99384963; called by muse, mutect2
- TRIM38 | c.392A>T p.D131V | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs1182611170; called by muse, mutect2
- ZDHHC11B | c.808G>C p.E270Q | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1175348274; called by muse, mutect2, varscan2
- AACS | c.1881+1G>T p.X627_splice | Splice Site (SNP) | VAF 20/147 reads (14%) | called by muse, mutect2, varscan2
- AKAP4 | c.1509G>T p.E503D | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); called by muse, mutect2
- ASPSCR1 | c.1348T>G p.F450V | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- CCDC153 | c.44A>T p.Q15L | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- CDKN2D | c.25G>A p.G9S | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2
- CEMIP | c.1907G>T p.G636V | Missense Mutation (SNP) | VAF 12/331 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2
- CERKL | c.1208A>C p.E403A (on ENST00000339098 / NM_001030311.2; = p.E377A on NM_201548.5) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- CNN2 | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 28/374 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CUL9 | c.1682A>C p.N561T | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2
- CUL9 | c.4687G>T p.G1563C | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DROSHA | c.2995T>C p.Y999H | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- E2F2 | c.927G>C p.E309D | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ELF3 | c.177G>C p.W59C | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FBLN1 | c.1385A>G p.Q462R | Missense Mutation (SNP) | VAF 57/517 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FYCO1 | c.2827G>A p.E943K | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- GCGR | c.949-2A>G p.X317_splice | Splice Site (SNP) | VAF 9/89 reads (10%) | called by muse, mutect2, varscan2
- GRB2 | c.556A>G p.M186V | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- MAPK9 | c.512G>C p.G171A | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- NLRX1 | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- NPHP3 | c.3847T>A p.L1283I | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PSMD9 | c.230A>G p.H77R | Missense Mutation (SNP) | VAF 9/214 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- RAB7A | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- RANBP9 | c.1722A>T p.E574D | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.815); called by muse, mutect2
- SIRT1 | c.1840del p.T614Lfs*7 | Frame Shift Del (DEL) | VAF 7/54 reads (13%) | called by mutect2, pindel, varscan2
- SLC25A39 | c.185C>T p.T62I | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.048); called by muse, mutect2
- SNCG | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2
- TIAL1 | c.372-2A>G p.X124_splice | Splice Site (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- TMEM26 | c.471A>G p.I157M | Missense Mutation (SNP) | VAF 15/171 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- AMPD3 | c.306C>T p.A102= (on ENST00000396553 / NM_001025389.2; = p.A111= on NM_000480.3) | Silent (SNP) | VAF 32/378 reads (8%) | called by muse, mutect2
- CACNA1H | c.2658C>T p.F886= | Silent (SNP) | VAF 24/358 reads (7%) | catalogued as rs1202009471; called by muse, mutect2
- CHD8 | c.3091A>C p.R1031= (on ENST00000646647 / NM_001170629.2; = p.R752= on NM_020920.4) | Silent (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- KLHL29 | c.2316C>T p.P772= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as rs1404395980; called by muse, mutect2
- SLC1A6 | c.1476C>T p.L492= | Silent (SNP) | VAF 16/128 reads (13%) | catalogued as COSV99693773; called by muse, mutect2, varscan2
- AC092865.4 | chr12:8390653 G>T | 5'Flank (SNP) | VAF 17/44 reads (39%) | catalogued as rs190105354; called by muse, varscan2
- ANKRD26 | c.1635+2119C>T | Intron (SNP) | VAF 6/60 reads (10%) | catalogued as rs1213133783; called by muse, mutect2, varscan2
- INKA1 | c.-21G>A | 5'UTR (SNP) | VAF 9/125 reads (7%) | called by muse, mutect2
- RN7SL484P | chr15:99792891 G>C | 3'Flank (SNP) | VAF 28/302 reads (9%) | called by muse, mutect2
- RPL13AP20 | n.399A>C | RNA (SNP) | VAF 54/545 reads (10%) | called by muse, mutect2
- SLC7A13 | c.1180-1001G>T | Intron (SNP) | VAF 14/136 reads (10%) | called by muse, mutect2
- TCF3 | c.1823-409A>C | Intron (SNP) | VAF 7/83 reads (8%) | called by muse, mutect2
- TMEM169 | c.*11A>T | 3'UTR (SNP) | VAF 18/198 reads (9%) | called by muse, mutect2
- XIAP | c.*4819T>C | 3'UTR (SNP) | VAF 16/181 reads (9%) | called by muse, mutect2
